Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8059, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8059-01A (Primary Tumor).

[page 1 of 5]
Case ID		ID

[page 2 of 5]
Gross

--

[page 3 of 5]
Microscopic Description	Diagnosis Details

[page 4 of 5]
Comments	Formatted Path Report	Laterality/location
	STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Fundus Tumor size: 7 x 7 x 0.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Lesser omentum Lymph nodes: 1/7 positive for metastasis (Intraabdominal 1/7) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	Fundus

[page 5 of 5]
	Date of excision

Source: NCI Genomic Data Commons file b438a3fd-856f-406d-9e85-baff668e5d90 (TCGA-BR-8059.C58DEF42-9A42-4B55-B4B6-6EF87CA4B6C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).